Somatic mutation profile of tumor specimen TCGA-05-4422-01A (aliquot TCGA-05-4422-01A-01D-1265-08) from TCGA case TCGA-05-4422, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-05-4422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bec378d-6375-4b08-9b90-e50d095e07e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4422-10A (Blood Derived Normal), aliquot TCGA-05-4422-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7da26466-6b9e-483d-af5b-94803e6e4a51

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.103_126del p.E35_R42del | In Frame Del (DEL) | VAF 13/58 reads (22%) | hotspot (GDC flag); called by mutect2, pindel
- STK11 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM116418, COSV58820283; called by muse, mutect2
- AC100868.1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV51845029; called by muse, mutect2, varscan2
- AC100868.1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV51838779, COSV99226191, COSV99226762; called by muse, varscan2
- ADAMTSL4 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs1172330874, COSV55000338; called by muse, mutect2, varscan2
- ADCY4 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs756925041, COSV60251947; called by muse, mutect2, varscan2
- ARHGEF6 | c.391T>A p.S131T | Missense Mutation (SNP) | VAF 131/236 reads (56%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); catalogued as COSV51692503; called by muse, mutect2, varscan2
- CA8 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs764581704, COSV58770526, COSV58772700; called by muse, mutect2, varscan2
- CCDC189 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV60312604; called by muse, mutect2, varscan2
- CDH26 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1166012594, COSV54848684; called by muse, mutect2, varscan2
- HGF | c.2057T>C p.M686T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV55951727; called by muse, mutect2, varscan2
- HTR3C | c.280-2A>T p.X94_splice | Splice Site (SNP) | VAF 33/73 reads (45%) | catalogued as COSV59176263; called by muse, mutect2, varscan2
- HYDIN | c.3839C>A p.T1280K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV66832972; called by muse, mutect2, varscan2
- IDI1 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | catalogued as COSV101191274; called by muse, mutect2
- KANK4 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs142004576; called by muse, mutect2, varscan2
- LAMC1 | c.4067G>T p.G1356V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51149084, COSV51168621; called by muse, mutect2, varscan2
- MYOF | c.3428G>C p.C1143S | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs761250319, COSV63705761, COSV63706079; called by muse, mutect2, varscan2
- PDGFRB | c.1178A>C p.H393P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as COSV55806530; called by muse, mutect2, varscan2
- PLD4 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV66915402; called by muse, mutect2, varscan2
- RFPL4B | c.675T>A p.N225K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV101480724; called by muse, mutect2, varscan2
- SCNN1G | c.582G>C p.M194I | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV55599699; called by muse, mutect2
- SCO2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs1439351743, COSV99329763; called by muse, mutect2, varscan2
- SEMA3F | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV50030960; called by muse, mutect2, varscan2
- SF1 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57115291; called by muse, mutect2, varscan2
- SON | c.5486C>A p.S1829Y | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51662280; called by muse, mutect2, varscan2
- SPTB | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67632811; called by muse, mutect2, varscan2
- TRIM71 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs1241571467, COSV67470528; called by muse, mutect2, varscan2
- TRMT12 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 19/191 reads (10%) | catalogued as COSV60777320; called by muse, mutect2, varscan2
- TRMT12 | c.1322G>C p.C441S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776928, COSV60777328; called by muse, mutect2
- USP15 | c.2089G>A p.E697K (on ENST00000280377 / NM_001351159.2; = p.E668K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV54794227; called by muse, mutect2, varscan2
- VPS18 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55030925; called by muse, mutect2, varscan2
- AOPEP | c.269del p.F90Sfs*55 | Frame Shift Del (DEL) | VAF 64/236 reads (27%) | called by mutect2, pindel, varscan2
- DHX15 | c.1938_1942del p.N647Hfs*2 | Frame Shift Del (DEL) | VAF 36/229 reads (16%) | called by mutect2, pindel, varscan2
- AAMP | c.351C>T p.F117= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as rs755606033, COSV50308108; called by muse, mutect2, varscan2
- AASS | c.2565G>A p.T855= | Silent (SNP) | VAF 144/512 reads (28%) | catalogued as rs1487551370, COSV62790569; called by muse, varscan2
- ABHD17B | c.732C>G p.L244= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV61008204; called by muse, mutect2, varscan2
- DNAH9 | c.8082G>T p.V2694= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as COSV52357018, COSV52378953; called by muse, mutect2, varscan2
- KIF4B | c.3480C>G p.V1160= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV70530080; called by muse, mutect2, varscan2
- MROH5 | c.1362G>A p.L454= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV71302026; called by muse, mutect2, varscan2
- MYO18B | c.6030G>A p.A2010= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs748527777, COSV59136698; called by muse, mutect2
- RYR2 | c.6306G>T p.L2102= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV63660761; called by muse, mutect2, varscan2
- SLITRK2 | c.786C>A p.L262= | Silent (SNP) | VAF 65/107 reads (61%) | catalogued as COSV59426581, COSV59428568; called by muse, mutect2, varscan2
- THEG | c.1008C>T p.I336= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs755521497, COSV61074148; called by muse, mutect2, varscan2
- TLR3 | c.813A>G p.L271= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs1229223752, COSV57169164; called by muse, mutect2, varscan2
- ZNF536 | c.1815G>C p.R605= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as COSV62823781, COSV62826910; called by muse, mutect2, varscan2
- NRXN1 | c.3719-1395C>T | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs1169668668, COSV100640636; called by muse, mutect2, varscan2
- SNORD115-8 | n.18C>G | RNA (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
